Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A3X7, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A3X7-01A (Primary Tumor).

Procurement Date: Laterality: Right

Path Report: THYROID CHECKLIST

Histologic type:

Papillary thyroid carcinoma, micrfollicular variant

Tumor size: 1 x 0.7 x 0.6cm

Tumor extent: penetrate to regional soft tissue

Tumor laterality: Right

Tumor focality: Multifocal

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9 5-17-12
RD

Just Synchronous Primary Nodules		X

5/14/12

Source: NCI Genomic Data Commons file 435b4446-9057-4517-9e6e-20c2dfdbffaf (TCGA-E8-A3X7.045AB42B-1C1B-4144-8038-9AE04F9339AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).